Somatic mutation profile of tumor specimen MP2PRT-PAUVZX-TMP1-A (aliquot MP2PRT-PAUVZX-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUVZX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,026 days).
Specimen MP2PRT-PAUVZX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62bccf1f-fc3f-4216-9c25-43a11d2c4850.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVZX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVZX-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87a4a59b-031c-4a9b-9339-b9ff5e50ba70

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 96/282 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CASC3 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 35/418 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748600426, COSV52868136; called by muse, mutect2
- GIGYF2 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs753733236, COSV65250787; called by muse, varscan2
- HSPG2 | c.6928G>A p.V2310I | Missense Mutation (SNP) | VAF 56/477 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs374301325; called by muse, varscan2
- MYOF | c.3686G>A p.R1229Q | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780085110; called by muse, mutect2, varscan2
- PKDREJ | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs781421433; called by muse, mutect2
- CCDC186 | c.1104A>G p.E368= | Splice Region (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CACNA1A | c.2328C>T p.S776= | Silent (SNP) | VAF 24/430 reads (6%) | called by muse, mutect2
- DNAH2 | c.10590G>T p.L3530= | Silent (SNP) | VAF 20/478 reads (4%) | called by muse, mutect2
- GTF2IRD1 | c.495C>T p.A165= | Silent (SNP) | VAF 49/845 reads (6%) | catalogued as rs782037332, COSV56088197; called by muse, mutect2
- TTC29 | c.933C>A p.L311= | Silent (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
